Somatic mutation profile of tumor specimen BA2534D (aliquot aq-BA2534D) from BEATAML1.0 case 2077, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.5 years (26,123 days).
Specimen BA2534D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf656107-f751-4ea1-a09e-1bba4e398358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2131D (Solid Tissue Normal), aliquot aq-BA2131D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3727fbe8-b07d-40b9-b0f9-fb57b57d8e42

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, RNA 2, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 38/306 reads (12%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, varscan2
- CACNA1D | c.3762G>C p.L1254F (on ENST00000350061 / NM_001128840.3; = p.L1274F on NM_000720.4) | Missense Mutation (SNP) | VAF 137/254 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV55440602; called by muse, mutect2, varscan2
- CERS3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 69/132 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52569670; called by muse, mutect2, varscan2
- CHIA | c.383G>A p.R128H (on ENST00000343320; = p.R20H on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs140031055; called by muse, mutect2, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by muse, mutect2, varscan2
- JRK | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1048716496; called by muse, mutect2, varscan2
- KCNMA1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1465957812; called by muse, varscan2
- MMRN2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100922469, COSV64401397; called by muse, mutect2, varscan2
- PHF6 | c.586-1G>A p.X196_splice (on ENST00000332070 / NM_032458.3; = p.X197_splice on NM_032335.3) | Splice Site (SNP) | VAF 21/334 reads (6%) | catalogued as COSV100136238, COSV59703967; called by muse, mutect2
- PIGS | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52023858; called by muse, mutect2, varscan2
- PRAG1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs769325354, COSV58162654; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- SLC30A2 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as rs144832711; called by muse, mutect2, varscan2
- WT1 | c.1330_1331insAGGCCTAGGCCCCCA p.C444delins* | Nonsense Mutation (INS) | VAF 66/201 reads (33%) | catalogued as COSV99070074; called by mutect2, pindel, varscan2
- WT1 | c.1102_1103insA p.R368Qfs*5 | Frame Shift Ins (INS) | VAF 86/151 reads (57%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, pindel*
- APOB | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD109 | c.2384_2387del p.T795Kfs*4 | Frame Shift Del (DEL) | VAF 88/172 reads (51%) | called by mutect2, pindel*, varscan2
- CLPX | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DST | c.1613G>T p.G538V (on ENST00000361203 / NM_001374722.1; = p.G212V on NM_001723.6) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM3 | c.1061T>A p.F354Y | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HEPH | c.2368A>C p.T790P (on ENST00000343002; = p.T523P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KAT2A | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MARCHF11 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NLRP1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by mutect2, varscan2
- NRXN1 | c.1019T>G p.V340G | Missense Mutation (SNP) | VAF 124/347 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NUP98 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PODN | c.1170C>A p.S390R (on ENST00000395871; = p.S342R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2
- PRR14 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ZBTB2 | c.1507T>C p.S503P | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- AHSA2P | n.1493del | RNA (DEL) | VAF 55/148 reads (37%) | called by mutect2, pindel, varscan2
- BX537318.2 | n.618_619insGGGG | RNA (INS) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- LEMD2 | c.-4G>C | 5'UTR (SNP) | VAF 71/172 reads (41%) | catalogued as rs757864405; called by muse, mutect2, varscan2
- MKS1 | c.190+25_190+26insGGGCC | Intron (INS) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- NUDT21 | c.-1C>T | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- POSTN | c.*24G>A | 3'UTR (SNP) | VAF 95/200 reads (48%) | called by muse, mutect2, varscan2
